Surgical pathology report (de-identified scan), TCGA case TCGA-H9-7775, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-H9-7775-01A (Primary Tumor).

[page 1 of 2]
Final Pathologic Diagnosis:

Prostate, prostatectomy:

Histologic type: Adenocarcinoma

Variant histology present: No

Prostate size: 5.0 x 5.0 x 4.3 cm; weight: 49 g

Gleason score (primary + secondary): 3 + 4 = 7

Primary pattern (%): 3 (95%)

Secondary pattern (%): 4 (5%)

Tertiary pattern (if present) (%): 0

Tumor quantitation:

Greatest dimension, largest tumor focus: 27 mm

Additional dimensions: 18 x 11 mm

Location, largest tumor focus: Right posterior

Multifocality: Yes

Greatest dimension, second largest focus: 24 mm

Location, second largest focus: Right anterior

Extraprostatic extension: No

Seminal vesicle invasion: No

Cancer at surgical margin: No

If no, closest distance with location: 1 mm, right posterior

Incised specimen: No

Apex involvement: No

Bladder neck involvement: No

Lymph-vascular invasion: No

Perineural invasion: No

Treatment effect on carcinoma: No

Other histologic findings: (list) High-grade prostatic intraepithelial neoplasia

Lymph nodes sampling submitted: No

Ancillary studies: No

Pathologic stage [REDACTED] pT2c, NX, MX

Gross Description:

The specimen is received fresh for tissue procurement, labeled with the patient's name and additionally labeled "prostate" and consists of a 49 gram, 4.3 cm in length by 5 x 5 cm prostate gland with attached bilateral seminal vesicles. The specimen is received previously inked as follows: Right side yellow, left side black, posterior red.

The distal margin of resection is coned and submitted in cassette 1. The proximal margin is coned and submitted in cassette 2.

The remaining prostate gland is sectioned from apex to base. The cut surface is pink-tan with diffuse nodularity surrounding the prostatic urethra. Sectioning

[page 2 of 2]
through the seminal vesicles and segments of vas deferens reveals a pink-tan, unremarkable cut surface.

Representative sections are submitted as follows:

- 1 apex, completely submitted;
- 2 bladder base, completely submitted;
- 3-14 right posterior prostate gland, apex to base, completely submitted;
- 15-25 left posterior prostate gland, apex to base, completely submitted;
- 26 right anterior, cross section 2;
- 27 left anterior, cross section 3;
- 28 right anterior, cross section 4;
- 29 left anterior, cross section 5;
- 30 right seminal vesicle-prostate interface;
- 31-32 additional right seminal vesicle;
- 33 left seminal vesicle-prostate interface;
- 34-35 additional left seminal vesicle.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Source: NCI Genomic Data Commons file 3b8e0201-74ea-4e29-a1da-3ec3575c1cf6 (TCGA-H9-7775.2A752788-15F1-4879-96A7-EAF5DFA6921D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).